Somatic mutation profile of tumor specimen TCGA-PL-A8LV-01A (aliquot TCGA-PL-A8LV-01A-21D-A41F-09) from TCGA case TCGA-PL-A8LV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medullary carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 54.1 years (19,746 days).
Specimen TCGA-PL-A8LV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b8a9b96-d855-482b-97bd-a45ff5a20468.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PL-A8LV-10A (Blood Derived Normal), aliquot TCGA-PL-A8LV-10A-01D-A41F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf171a35-7213-4e87-8237-96e93a8ded86

The open-access MAF lists 110 somatic variants for this specimen: 82 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 27, Splice Site 3, Nonsense Mutation 3, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 6/13 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- A2M | c.976A>G p.I326V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.13); catalogued as rs769791745, COSV100588877; called by muse, mutect2, varscan2
- AC023055.1 | c.1146G>C p.E382D | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.365); catalogued as COSV100278543, COSV100278631; called by muse, mutect2, varscan2
- ADARB2 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs1225574207, COSV101187133; called by muse, mutect2, varscan2
- ALDOC | c.719G>A p.C240Y | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.472); catalogued as COSV99257168; called by muse, mutect2, varscan2
- ANKRD30A | c.1223G>T p.W408L (on ENST00000611781; = p.W352L on NM_052997.2) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.307); catalogued as COSV100654185; called by muse, mutect2, varscan2
- APLF | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as rs755954160, COSV58149020; called by muse, mutect2, varscan2
- APOBEC3F | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.241); catalogued as rs369091002; called by muse, mutect2, varscan2
- ATP11A | c.2155G>C p.E719Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.593); catalogued as COSV99369508; called by muse, mutect2, varscan2
- C2orf16 | c.4680C>A p.N1560K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1020340149, COSV100820913, COSV100821039; called by muse, mutect2
- CACUL1 | c.1093T>C p.S365P | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs1472639308, COSV100975751; called by muse, mutect2, varscan2
- CD248 | c.1727G>A p.R576K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100256701, COSV60937801; called by muse, mutect2, varscan2
- CDC20 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1222189741, COSV100196591; called by muse, mutect2, varscan2
- CDH4 | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as rs756845197, COSV64662428; called by muse, mutect2, varscan2
- CEP162 | c.1209C>A p.N403K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100003161; called by muse, mutect2, varscan2
- CEP290 | c.2797G>C p.G933R | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100469434; called by muse, mutect2
- CPSF4 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs201226770, COSV99462606; called by muse, mutect2, varscan2
- CRTC2 | c.1789C>G p.P597A | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100339281; called by muse, mutect2, varscan2
- CUL1 | c.2110G>C p.E704Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100296833, COSV100296860; called by muse, mutect2, varscan2
- DCAF8 | c.469G>C p.A157P | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV100470716; called by muse, mutect2
- DIS3L | c.1830C>G p.F610L (on ENST00000319212 / NM_001143688.3; = p.F527L on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100055488; called by muse, mutect2, varscan2
- FANCI | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as COSV100168371; called by muse, mutect2, varscan2
- FARP1 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.492); catalogued as rs758237923, COSV100131707; called by muse, mutect2, varscan2
- FKTN | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.195); catalogued as COSV99795528; called by muse, mutect2
- GFPT2 | c.1417G>T p.V473L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs767726394, COSV53807569, COSV99517954; called by muse, mutect2, varscan2
- GFPT2 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as COSV53812682; called by muse, mutect2, varscan2
- GLA | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869312407, CM002608, CM003752, CM085978, COSV99516524, COSV99516586; called by muse, mutect2, varscan2
- GNL3 | c.338G>C p.C113S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV101187267; called by muse, mutect2, varscan2
- GON4L | c.4198G>C p.G1400R | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV99675296; called by muse, mutect2, varscan2
- GPATCH4 | c.168+1G>T p.X56_splice | Splice Site (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100576979; called by muse, mutect2, varscan2
- GPKOW | c.243G>T p.Q81H | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); catalogued as COSV99332765; called by muse, mutect2, varscan2
- GPM6B | c.495G>T p.W165C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100366431; called by muse, mutect2, varscan2
- HERC1 | c.10807G>C p.D3603H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV101496790, COSV71249545; called by muse, mutect2, varscan2
- HLTF | c.1378G>T p.A460S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.031); catalogued as COSV100027033; called by muse, mutect2, varscan2
- IL31RA | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV99763426; called by muse, mutect2, varscan2
- IQGAP3 | c.73A>G p.R25G | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100752272; called by muse, mutect2, varscan2
- IREB2 | c.2143T>G p.S715A | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV99359626; called by muse, mutect2, varscan2
- ITGA1 | c.596G>C p.R199T | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV50885231, COSV50894195, COSV99251868; called by muse, mutect2, varscan2
- JAK3 | c.1976G>C p.G659A | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV101512992, COSV71686018; called by muse, mutect2, varscan2
- KAZN | c.819G>T p.E273D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100748045; called by muse, mutect2, varscan2
- KHDC4 | c.1394C>G p.T465R | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV100850840; called by muse, mutect2, varscan2
- KIAA0100 | c.1441C>A p.Q481K | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV101197374, COSV66496972; called by muse, mutect2, varscan2
- LAMA3 | c.2373C>G p.Y791* | Nonsense Mutation (SNP) | VAF 28/52 reads (54%) | catalogued as COSV100557414; called by muse, mutect2, varscan2
- LCA5L | c.142A>C p.S48R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99903810; called by mutect2, varscan2
- MAN1A1 | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100870412; called by muse, mutect2, varscan2
- MMP24 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs777650805, COSV55771949; called by muse, mutect2, varscan2
- MUC17 | c.1742T>C p.L581P | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100074542; called by muse, mutect2, varscan2
- MUC4 | c.1812A>T p.R604S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.234); catalogued as COSV100641733; called by muse, mutect2, varscan2
- NAA10 | c.387-2A>T p.X129_splice | Splice Site (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100604174; called by muse, mutect2, varscan2
- NIPAL4 | c.571A>G p.T191A | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV100357265; called by muse, mutect2, varscan2
- OBSCN | c.8567C>T p.P2856L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV52839406; called by muse, mutect2, varscan2
- PHF21B | c.794A>G p.K265R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV100504015; called by muse, mutect2, varscan2
- PIN4 | c.113G>A p.G38E (on ENST00000664196; = p.G13E on NM_006223.4) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99512541; called by muse, mutect2, varscan2
- PIP5K1B | c.622A>G p.T208A | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99599459; called by muse, mutect2
- PLSCR5 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs372370688, COSV71649018; called by muse, mutect2, varscan2
- POGLUT2 | c.790G>C p.D264H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101050815; called by muse, mutect2, varscan2
- PPEF2 | c.1032C>G p.I344M | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.3); PolyPhen benign (0.214); catalogued as COSV54425277; called by muse, mutect2, varscan2
- PPP1R7 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99298100; called by mutect2, varscan2
- PRR35 | c.1054A>T p.S352C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV99552214; called by muse, mutect2, varscan2
- PRUNE2 | c.4818A>T p.R1606S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV100944966; called by muse, mutect2, varscan2
- PTCD3 | c.368C>G p.S123* | Nonsense Mutation (SNP) | VAF 7/109 reads (6%) | catalogued as COSV99606542; called by muse, mutect2
- RANBP3 | c.269G>C p.R90P | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.162); catalogued as COSV99222443; called by muse, mutect2, varscan2
- RBM4B | c.890C>G p.S297C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV100026505; called by muse, mutect2, varscan2
- RBMX | c.845G>C p.R282T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100284877; called by muse, mutect2, varscan2
- RPL23A | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as COSV99411852; called by muse, mutect2, varscan2
- SAV1 | c.346T>C p.F116L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1261369126, COSV100220849; called by muse, mutect2, varscan2
- SIRPG | c.318C>G p.I106M | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53809165, COSV99403889; called by muse, mutect2, varscan2
- SMTN | c.1537A>C p.N513H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.259); catalogued as COSV100294797; called by muse, mutect2, varscan2
- SPPL3 | c.610-2A>C p.X204_splice | Splice Site (SNP) | VAF 12/17 reads (71%) | catalogued as COSV100793727; called by muse, mutect2
- SVEP1 | c.4043A>T p.E1348V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100238746; called by muse, mutect2, varscan2
- THEM4 | c.346G>C p.D116H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV100916956; called by muse, mutect2, varscan2
- TMC4 | c.800T>C p.L267P (on ENST00000617472 / NM_001145303.3; = p.L261P on NM_144686.4) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100000798; called by muse, mutect2, varscan2
- TMEM131 | c.1834G>C p.E612Q | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0.018); catalogued as COSV51775921; called by muse, mutect2
- TRPM4 | c.3568G>A p.A1190T | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs1163408519, COSV99053690; called by muse, mutect2
- USP20 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100204627; called by muse, mutect2, varscan2
- USP46 | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as COSV101484299, COSV71513161; called by muse, mutect2, varscan2
- ZC3H11A | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs1332120001, COSV100142592; called by muse, mutect2, varscan2
- ZNF185 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100248580; called by muse, mutect2, varscan2
- ZNF425 | c.864C>A p.N288K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV100955561; called by muse, mutect2, varscan2
- ALDH1L2 | c.254del p.G85Afs*18 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | called by mutect2, pindel, varscan2
- EP300 | c.1060del p.R354Gfs*8 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | called by mutect2, pindel, varscan2
- SZT2 | c.2833G>A p.A945T | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.05); called by muse, mutect2
- ACOX2 | c.594A>C p.S198= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as COSV100250257; called by muse, mutect2, varscan2
- ADGRF5 | c.690G>C p.V230= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV99346151; called by muse, mutect2, varscan2
- AKAP6 | c.2790C>G p.L930= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99797986, COSV99803177; called by mutect2, varscan2
- AKAP6 | c.5145T>C p.N1715= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs756018151, COSV99803179; called by muse, mutect2, varscan2
- ARHGEF12 | c.1944G>A p.Q648= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100755118; called by muse, varscan2
- ARSA | c.1125C>A p.L375= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV53350239, COSV99332461; called by muse, mutect2
- ATP13A2 | c.2931C>T p.L977= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100454333; called by muse, mutect2, varscan2
- ATP1B4 | c.400C>T p.L134= (on ENST00000218008 / NM_001142447.3; = p.L130= on NM_012069.5) | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99486445; called by muse, mutect2, varscan2
- CENPB | c.1083C>G p.L361= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100713488, COSV100713580; called by muse, mutect2, varscan2
- CXCR5 | c.141C>T p.A47= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV99419870; called by muse, mutect2, varscan2
- CYP11A1 | c.1062A>C p.A354= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV99166111; called by muse, mutect2, varscan2
- DCUN1D2 | c.171G>A p.R57= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV60260986; called by muse, mutect2
- DMGDH | c.1356C>T p.N452= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs1410209499, COSV99669348; called by muse, mutect2, varscan2
- EIF3H | c.891T>C p.P297= | Silent (SNP) | VAF 4/73 reads (5%) | called by muse, mutect2
- GGTLC2 | c.30C>G p.L10= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV101312250; called by muse, mutect2, varscan2
- HOOK2 | c.1320C>G p.P440= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV99317778; called by muse, mutect2, varscan2
- MPND | c.1161C>G p.L387= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99515232; called by muse, mutect2
- OR4D6 | c.27G>A p.V9= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as COSV100271787; called by muse, mutect2, varscan2
- OR56A3 | c.27C>A p.L9= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV61569390; called by muse, mutect2, varscan2
- PGM2L1 | c.366T>C p.T122= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs370744378; called by muse, mutect2, varscan2
- PPFIA4 | c.3015G>C p.L1005= (on ENST00000447715; = p.L1006= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as COSV99690823; called by muse, mutect2
- RAB11FIP4 | c.192C>T p.N64= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs538922793, COSV100365644; called by muse, mutect2, varscan2
- RBM5 | c.2410C>A p.R804= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV100762427, COSV61738881; called by muse, mutect2
- THEM5 | c.330A>G p.K110= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV100917274; called by muse, mutect2, varscan2
- TMPRSS7 | c.2286T>C p.C762= (on ENST00000452346; = p.C636= on NM_001042575.2) | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs1176302172, COSV101340146; called by muse, mutect2, varscan2
- TOMM40 | c.531C>T p.A177= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs946867496, COSV99375185; called by muse, mutect2, varscan2
- ZNF565 | c.1086G>C p.L362= (on ENST00000355114; = p.L322= on NM_152477.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV100411959; called by muse, mutect2, varscan2
- LRMDA | c.131+114018C>A | Intron (SNP) | VAF 7/69 reads (10%) | catalogued as COSV101130152; called by muse, mutect2, varscan2
